Somatic mutation profile of tumor specimen TCGA-CF-A3MI-01A (aliquot TCGA-CF-A3MI-01A-11D-A20D-08) from TCGA case TCGA-CF-A3MI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: Low Grade; Age at diagnosis: 62.2 years (22,716 days).
Specimen TCGA-CF-A3MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3deee8ab-b0fa-4baa-9932-077b8ac81742.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CF-A3MI-10A (Blood Derived Normal), aliquot TCGA-CF-A3MI-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc4d38b0-577f-40ff-b29e-92d4c5d96105

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP1G1 | c.882G>C p.L294F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55486975; called by muse, mutect2, varscan2
- ARAP1 | c.2302G>C p.E768Q (on ENST00000393609 / NM_001040118.2; = p.E523Q on NM_015242.4) | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV61990189; called by muse, mutect2, varscan2
- ARHGAP11A | c.2378A>T p.K793I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV55705590; called by muse, mutect2, varscan2
- ARID2 | c.3617C>T p.T1206M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs371554995, COSV57599537; called by muse, mutect2, varscan2
- ASB15 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as rs952485463, COSV51924713; called by muse, mutect2
- ATXN1 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as COSV55211723; called by muse, mutect2, varscan2
- C11orf58 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.753); catalogued as COSV57178314; called by muse, mutect2, varscan2
- CDS1 | c.637A>G p.M213V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV55687210; called by muse, mutect2, varscan2
- CNTRL | c.4774C>T p.Q1592* | Nonsense Mutation (SNP) | VAF 81/98 reads (83%) | catalogued as COSV53051823; called by muse, mutect2, varscan2
- COL7A1 | c.3507G>C p.L1169F | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); catalogued as COSV60393122; called by muse, mutect2, varscan2
- CXCR3 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV65461709; called by muse, mutect2, varscan2
- CYP11B2 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs377490679, CM143855, COSV59995250; called by muse, mutect2, varscan2
- DLG4 | c.2092G>A p.E698K (on ENST00000399506 / NM_001321075.3; = p.E741K on NM_001365.4) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57237270; called by muse, mutect2, varscan2
- FLNB | c.7369G>A p.G2457S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs142229998, COSV99913080; called by muse, mutect2, varscan2
- GPC3 | c.1691T>G p.L564R | Missense Mutation (SNP) | VAF 61/63 reads (97%) | SIFT tolerated (0.36); PolyPhen benign (0.164); catalogued as COSV63661033; called by muse, mutect2, varscan2
- GRM1 | c.2399C>A p.A800D | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51119234; called by muse, mutect2, varscan2
- HOXC13 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54498348; called by muse, mutect2
- JHY | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56218434; called by muse, mutect2, varscan2
- KMT2C | c.1066C>G p.Q356E | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV100068483, COSV51421061, COSV51457733; called by muse, mutect2
- LDHAL6B | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV55684043; called by muse, mutect2, varscan2
- METTL21A | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336954438, COSV55881351; called by muse, mutect2, varscan2
- MINDY3 | c.731-1G>A p.X244_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV53219076; called by muse, mutect2, varscan2
- MORC2 | c.1652G>A p.R551K (on ENST00000397641 / NM_001303256.3; = p.R489K on NM_014941.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53197269; called by muse, mutect2, varscan2
- MUC16 | c.37778A>G p.Y12593C | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV67453995; called by muse, mutect2, varscan2
- NIBAN1 | c.986-1G>A p.X329_splice | Splice Site (SNP) | VAF 37/162 reads (23%) | catalogued as COSV62283646; called by muse, mutect2, varscan2
- OR5D13 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs369729738, COSV62332785; called by muse, mutect2, varscan2
- OTUD7A | c.824C>T p.T275M (on ENST00000307050 / NM_001382637.1; = p.T268M on NM_130901.3) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as rs776882002, COSV61037038; called by muse, mutect2, varscan2
- PAIP1 | c.338T>A p.M113K | Missense Mutation (SNP) | VAF 74/147 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV59085519; called by muse, mutect2, varscan2
- PPP4R3B | c.2159A>T p.D720V (on ENST00000616407 / NM_001122964.3; = p.D635V on NM_020463.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55402972; called by muse, mutect2, varscan2
- RBBP6 | c.941T>G p.F314C | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60503992; called by muse, mutect2
- RFX3 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56510377; called by muse, mutect2, varscan2
- SORL1 | c.5252C>T p.P1751L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1208966716, COSV52751372; called by muse, mutect2, varscan2
- STAG2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 45/45 reads (100%) | catalogued as COSV54350913; called by muse, mutect2, varscan2
- TBL1Y | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60732606; called by muse, mutect2, varscan2
- TBX4 | c.219G>C p.E73D | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53605980; called by muse, mutect2
- TCHHL1 | c.1489G>C p.E497Q | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV64285218; called by muse, mutect2, varscan2
- TCHHL1 | c.1161G>C p.M387I | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV64285223; called by muse, mutect2, varscan2
- TEX15 | c.2029G>A p.E677K (on ENST00000256246; = p.E1060K on NM_001350162.2) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV56343637; called by muse, mutect2, varscan2
- TLR3 | c.2348C>G p.S783C | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV57167934; called by muse, mutect2, varscan2
- TTC16 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs772802472, COSV64777888; called by muse, mutect2, varscan2
- USP20 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.257); catalogued as rs765681428, COSV59611328; called by muse, mutect2, varscan2
- ZNF207 | c.1145A>G p.Y382C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58299252; called by muse, mutect2, varscan2
- ZNF677 | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61719741; called by muse, mutect2, varscan2
- KDM2B | c.2110G>T p.E704* | Nonsense Mutation (SNP) | VAF 16/128 reads (13%) | called by muse, varscan2
- MARK2 | c.913_916del p.N305Wfs*8 | Frame Shift Del (DEL) | VAF 89/216 reads (41%) | called by mutect2, pindel, varscan2
- PILRB | c.267dup p.H90Sfs*131 | Frame Shift Ins (INS) | VAF 41/157 reads (26%) | called by pindel, varscan2
- SPAG6 | c.1206dup p.A403Sfs*16 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- TCTE1 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ARPC5L | c.279T>C p.I93= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV52346512; called by muse, mutect2
- CDK5R1 | c.606C>T p.V202= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV55577890; called by muse, mutect2, varscan2
- GEMIN4 | c.462C>T p.A154= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs151264305; called by muse, mutect2
- LRRC8A | c.259C>T p.L87= | Silent (SNP) | VAF 63/74 reads (85%) | catalogued as COSV52184819; called by muse, mutect2, varscan2
- LRRC8A | c.978C>T p.I326= | Silent (SNP) | VAF 72/86 reads (84%) | catalogued as rs373351369; called by muse, mutect2, varscan2
- LRRC8A | c.1638C>G p.L546= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as COSV52184877; called by muse, mutect2, varscan2
- MON1A | c.1374C>T p.G458= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56559905; called by muse, varscan2
- MYH10 | c.1137G>A p.Q379= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV52597176; called by muse, mutect2, varscan2
- OBSCN | c.5742C>T p.G1914= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs1195818578, COSV52755167; called by muse, mutect2, varscan2
- PCDHB6 | c.1773C>T p.D591= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV99169956; called by muse, mutect2, varscan2
- PDZRN3 | c.2532C>T p.D844= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs371635820, COSV55211103; called by muse, mutect2, varscan2
- POLRMT | c.249G>A p.V83= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV74056302; called by muse, mutect2, varscan2
- SOGA3 | c.2583C>T p.D861= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs374876819, COSV64105653; called by muse, mutect2, varscan2
- SPDYE3 | c.1428T>C p.S476= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV60106851; called by muse, mutect2, varscan2
- STXBP5 | c.204A>G p.V68= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV51649528; called by muse, mutect2, varscan2
- TGM6 | c.2097C>T p.I699= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs781184549, COSV52478266; called by muse, mutect2, varscan2
- TRIM68 | c.1194G>C p.L398= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV56167974, COSV56168457, COSV56169514; called by muse, mutect2, varscan2
- ZNF629 | c.813C>T p.F271= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV52697830; called by muse, mutect2, varscan2
- PTPRK | c.578-1106C>G | Intron (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
